Somatic mutation profile of tumor specimen TCGA-ET-A3BW-01A (aliquot TCGA-ET-A3BW-01A-11D-A19J-08) from TCGA case TCGA-ET-A3BW, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 30.2 years (11,032 days).
Specimen TCGA-ET-A3BW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 48bf1f44-f3ff-4c5e-a388-95ef1ec5db71.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ET-A3BW-10A (Blood Derived Normal), aliquot TCGA-ET-A3BW-10A-01D-A19M-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0d2b71e9-88f7-4b16-9d35-5c548a884b62

The open-access MAF lists 7 somatic variants for this specimen: 3 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, Silent 2, Intron 1, Frame Shift Del 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 42/83 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- C6orf89 | c.814G>T p.V272L (on ENST00000373685; = p.V279L on NM_152734.4) | Missense Mutation (SNP) | VAF 4/72 reads (6%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV100769674; called by muse, mutect2
- PPM1D | c.1218del p.C407Vfs*2 | Frame Shift Del (DEL) | VAF 29/93 reads (31%) | called by mutect2, pindel, varscan2
- FGFR1 | c.222G>A p.A74= | Silent (SNP) | VAF 5/22 reads (23%) | catalogued as rs748896706, COSV58330057; called by muse, mutect2, varscan2
- HSPA5 | c.1476T>G p.R492= | Silent (SNP) | VAF 17/125 reads (14%) | catalogued as COSV52334349; called by muse, mutect2, varscan2
- TPM4 | c.*195C>T | 3'UTR (SNP) | VAF 12/54 reads (22%) | catalogued as COSV56288235; called by muse, mutect2, varscan2
- TTN | c.10361-3907T>C | Intron (SNP) | VAF 47/125 reads (38%) | catalogued as COSV59932831; called by muse, mutect2, varscan2
